Somatic mutation profile of tumor specimen C3L-07202-01 (aliquot CPT0407650010) from CPTAC case C3L-07202, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.5 years (27,564 days).
Specimen C3L-07202-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2a0bc33-1b89-4529-9c94-b875b45c08d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07202-31 (Blood Derived Normal), aliquot CPT0408730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/581539db-55ce-4d7b-8f7d-e875ebe83d3f

The open-access MAF lists 50 somatic variants for this specimen: 34 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 13, Nonsense Mutation 3, Frame Shift Ins 2, Intron 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 77/214 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60096069; called by muse, mutect2, varscan2
- BAHCC1 | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as rs1555653183; called by muse, mutect2, varscan2
- CARNS1 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 171/339 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs569391532, COSV57130037; called by muse, mutect2, varscan2
- CCDC144A | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs776066736, COSV60702506; called by muse, mutect2, varscan2
- CHST1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 86/100 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV57323162; called by muse, mutect2, varscan2
- CYP4F2 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs758269454, COSV99685920; called by muse, mutect2, varscan2
- FOXS1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs555540522, COSV54066147; called by mutect2, varscan2
- GBF1 | c.4672C>T p.R1558W (on ENST00000369983 / NM_001377137.1; = p.R1557W on NM_004193.3) | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200951370, COSV64149699; called by muse, mutect2, varscan2
- IGLV8-61 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 137/343 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs535823475, COSV66503099; called by muse, mutect2, varscan2
- KCNMA1 | c.3295C>T p.R1099C (on ENST00000286628 / NM_001161352.2; = p.R1041C on NM_002247.4) | Missense Mutation (SNP) | VAF 247/471 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV54257454; called by muse, mutect2, varscan2
- MYCBP2 | c.3040A>T p.T1014S (on ENST00000357337; = p.T1052S on NM_015057.5) | Missense Mutation (SNP) | VAF 159/359 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as rs534169029; called by muse, mutect2, varscan2
- MYO1C | c.214C>T p.R72W (on ENST00000648651 / NM_001080779.2; = p.R37W on NM_033375.5) | Missense Mutation (SNP) | VAF 143/321 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs866381057, COSV62999221; called by muse, mutect2, varscan2
- PATJ | c.4696G>A p.G1566R | Missense Mutation (SNP) | VAF 64/107 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370745996; called by muse, mutect2, varscan2
- PDGFRA | c.1730C>G p.P577R | Missense Mutation (SNP) | VAF 308/326 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57270321, COSV57277054; called by muse, mutect2, varscan2
- RASAL3 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 75/186 reads (40%) | catalogued as rs1051135881; called by muse, mutect2, varscan2
- RNF208 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 145/435 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1219530147, COSV61287560; called by muse, mutect2, varscan2
- SLC26A3 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 214/490 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs771347047; called by muse, mutect2, varscan2
- A2M | c.1355T>C p.F452S | Missense Mutation (SNP) | VAF 152/334 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, varscan2
- ABHD2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AMBRA1 | c.2595G>A p.W865* (on ENST00000458649 / NM_001367468.1; = p.W775* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 91/110 reads (83%) | called by muse, mutect2, varscan2
- CAPN5 | c.1808A>G p.N603S (on ENST00000456580; = p.N563S on NM_004055.5) | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CCDC168 | c.15457A>G p.S5153G | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- CDKN2C | c.49dup p.D17Gfs*7 | Frame Shift Ins (INS) | VAF 110/179 reads (61%) | called by mutect2, pindel, varscan2
- CFAP43 | c.1148T>C p.L383P | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DHX37 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DOP1B | c.6786_6787insAT p.D2263Mfs*20 | Frame Shift Ins (INS) | VAF 159/460 reads (35%) | called by mutect2, pindel, varscan2
- GSK3B | c.1096+2dup | Splice Region (INS) | VAF 44/104 reads (42%) | called by mutect2, pindel, varscan2
- IPO7 | c.1414A>G p.M472V | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NKX2-2 | c.524G>A p.W175* | Nonsense Mutation (SNP) | VAF 182/631 reads (29%) | called by muse, mutect2, varscan2
- SAP25 | c.11T>C p.L4P (on ENST00000538735; = p.L102P on NM_001168682.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- SARDH | c.869C>G p.A290G | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SLC22A6 | c.1254C>A p.D418E | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SMARCA4 | c.1684G>C p.A562P | Missense Mutation (SNP) | VAF 263/602 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ANP32E | c.807G>A p.*269= | Silent (SNP) | VAF 93/181 reads (51%) | catalogued as rs1365941937; called by muse, mutect2, varscan2
- ECSIT | c.1191C>T p.T397= | Silent (SNP) | VAF 125/280 reads (45%) | catalogued as rs767582209; called by muse, mutect2, varscan2
- FNDC1 | c.3852C>T p.R1284= | Silent (SNP) | VAF 16/448 reads (4%) | catalogued as COSV51930979; called by muse, mutect2
- FNDC1 | c.5385C>T p.F1795= | Silent (SNP) | VAF 65/244 reads (27%) | catalogued as rs571734975, COSV51932133; called by muse, mutect2, varscan2
- FZD1 | c.1638G>A p.V546= | Silent (SNP) | VAF 196/431 reads (45%) | called by muse, mutect2, varscan2
- METAP1D | c.933G>A p.S311= | Silent (SNP) | VAF 163/351 reads (46%) | called by muse, mutect2, varscan2
- OR6B3 | c.780C>A p.V260= | Silent (SNP) | VAF 133/285 reads (47%) | called by muse, mutect2, varscan2
- PLEKHG6 | c.642C>T p.S214= | Silent (SNP) | VAF 63/116 reads (54%) | catalogued as rs1457936454; called by muse, mutect2, varscan2
- TNS2 | c.309C>A p.T103= (on ENST00000314250 / NM_170754.4; = p.T113= on NM_015319.2) | Silent (SNP) | VAF 117/307 reads (38%) | called by muse, mutect2, varscan2
- WDR87 | c.4956C>T p.S1652= | Silent (SNP) | VAF 138/325 reads (42%) | called by muse, mutect2, varscan2
- ZNF410 | c.69A>G p.P23= | Silent (SNP) | VAF 48/93 reads (52%) | called by muse, mutect2, varscan2
- ZNF598 | c.2580G>A p.A860= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs372519290; called by muse, mutect2, varscan2
- ZNF80 | c.582C>T p.C194= | Silent (SNP) | VAF 94/210 reads (45%) | catalogued as rs774294338, COSV57360776, COSV57361810; called by muse, mutect2
- CLEC18B | c.877+138G>A | Intron (SNP) | VAF 33/386 reads (9%) | called by muse, mutect2, varscan2
- ISCA1 | c.-32dup | 5'UTR (INS) | VAF 231/822 reads (28%) | catalogued as rs1564011540; called by mutect2, pindel, varscan2
- SPG7 | c.183+272C>G | Intron (SNP) | VAF 166/365 reads (45%) | called by muse, mutect2, varscan2
